Somatic mutation profile of tumor specimen C3L-01672-01 (aliquot CPT0172460011) from CPTAC case C3L-01672, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IIIA; FIGO stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 53.6 years (19,576 days).
Specimen C3L-01672-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b7e1337-297e-44a1-8ee5-a634a0f88bc8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01672-71 (Blood Derived Normal), aliquot CPT0172490002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/765198d2-efa3-4fe3-8188-2b2adc7c575b

The open-access MAF lists 265 somatic variants for this specimen: 171 protein-altering or splice-affecting, 65 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 118, Silent 65, Frame Shift Del 31, Intron 12, Nonsense Mutation 9, 3'UTR 6, Frame Shift Ins 6, 3'Flank 4, RNA 4, Splice Region 3, 5'Flank 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYNC1H1 | c.1793G>A p.R598H | Missense Mutation (SNP) | VAF 149/324 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs879254085, CM151465; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NKX6-2 | c.234del p.L79Cfs*109 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as rs765650727; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 184/233 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121909218, CM115947, CM971272, COSV64289566, COSV64291659; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.4595G>T p.R1532L (on ENST00000614293; = p.R1502L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 138/314 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.428); catalogued as COSV99688408; called by muse, varscan2
- ADAMTS20 | c.2355del p.E786Kfs*86 | Frame Shift Del (DEL) | VAF 77/213 reads (36%) | catalogued as rs1177283960; called by mutect2, pindel, varscan2
- ADAMTS5 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 88/200 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs1381117530, COSV53175273; called by muse, mutect2, varscan2
- ARHGAP27 | c.1972G>A p.V658M (on ENST00000428638 / NM_001282290.1; = p.V317M on NM_199282.3) | Missense Mutation (SNP) | VAF 223/467 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs368827618; called by muse, mutect2, varscan2
- ATAD2B | c.1404del p.F468Lfs*9 | Frame Shift Del (DEL) | VAF 102/277 reads (37%) | catalogued as rs866490133; called by mutect2, varscan2
- CACNA1G | c.3709C>T p.R1237C | Missense Mutation (SNP) | VAF 21/249 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs765212113, COSV61728872; called by muse, mutect2
- CCIN | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 34/352 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as rs1447888896; called by muse, mutect2
- CDH20 | c.2393C>T p.A798V | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV53007413; called by muse, mutect2, varscan2
- CDKL5 | c.2684C>T p.P895L | Missense Mutation (SNP) | VAF 48/232 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.578); catalogued as rs587783157, COSV66111782, COSV66113108; called by muse, mutect2, varscan2
- CHD1 | c.3566G>A p.R1189Q | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as COSV52336710; called by muse, mutect2
- CSMD3 | c.635G>A p.G212D | Missense Mutation (SNP) | VAF 98/766 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52199046; called by muse, mutect2
- CWF19L2 | c.287del p.K96Rfs*41 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs772257590; called by mutect2, varscan2
- CYP2J2 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 35/134 reads (26%) | catalogued as rs750655796, COSV64606648; called by muse, mutect2, varscan2
- EDN1 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 36/416 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as rs777403291, COSV65080445; called by muse, mutect2
- ENTPD6 | c.661G>A p.G221R | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs368327763, COSV61751596; called by muse, mutect2, varscan2
- EPRS1 | c.4150C>T p.R1384* | Nonsense Mutation (SNP) | VAF 91/202 reads (45%) | catalogued as rs771013981, COSV100859577; called by muse, mutect2, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 10/85 reads (12%) | catalogued as rs753821453; called by mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 148/763 reads (19%) | catalogued as rs775950025; called by mutect2, varscan2
- FAAH2 | c.98del p.G33Vfs*12 | Frame Shift Del (DEL) | VAF 45/194 reads (23%) | catalogued as COSV100887477; called by mutect2, pindel, varscan2
- FAN1 | c.277A>G p.T93A | Missense Mutation (SNP) | VAF 37/297 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62950462; called by muse, mutect2, varscan2
- FCRLA | c.953C>T p.P318L (on ENST00000367959; = p.P295L on NM_032738.4) | Missense Mutation (SNP) | VAF 25/368 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs762589067, COSV52685803, COSV99376552; called by muse, mutect2
- HCN4 | c.2129G>A p.R710H | Missense Mutation (SNP) | VAF 18/456 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs961219559; called by muse, mutect2
- HECTD4 | c.11537G>A p.R3846H | Missense Mutation (SNP) | VAF 112/302 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs765073403, COSV101108407; called by muse, mutect2, varscan2
- HECTD4 | c.9718del p.A3240Rfs*26 | Frame Shift Del (DEL) | VAF 38/152 reads (25%) | catalogued as rs754540615; called by mutect2, varscan2
- HERC2 | c.12356G>A p.R4119H | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1380688410; called by muse, mutect2, varscan2
- HIP1 | c.2543T>C p.I848T | Missense Mutation (SNP) | VAF 13/243 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as rs1371447965; ClinVar: uncertain significance; called by muse, mutect2
- HNRNPDL | c.1229del p.G410Vfs*25 | Frame Shift Del (DEL) | VAF 117/361 reads (32%) | catalogued as COSV99040410; called by mutect2, pindel, varscan2
- HTR1B | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 42/362 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV64051212, COSV64051303; called by muse, mutect2, varscan2
- IRX2 | c.230_232dup p.A77dup | In Frame Ins (INS) | VAF 8/30 reads (27%) | catalogued as rs751032410; called by mutect2, varscan2
- JAKMIP1 | c.2297G>A p.R766H | Missense Mutation (SNP) | VAF 84/397 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV68950764, COSV68952032; called by muse, mutect2, varscan2
- KCNC1 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 25/605 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV56391827; called by muse, mutect2
- KCND2 | c.92del p.P31Rfs*15 | Frame Shift Del (DEL) | VAF 78/208 reads (38%) | catalogued as rs1562993378, COSV100474030, COSV58578960; called by mutect2, pindel, varscan2
- KMT2B | c.6832G>A p.V2278I | Missense Mutation (SNP) | VAF 104/272 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs746054083; called by muse, varscan2
- LDB2 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 148/552 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.107); catalogued as rs1480863984, COSV100453424, COSV58766987; called by mutect2, varscan2
- LDB3 | c.59del p.G20Afs*41 | Frame Shift Del (DEL) | VAF 106/318 reads (33%) | catalogued as rs1308589918; called by mutect2, pindel, varscan2
- LOXL3 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs772009677; called by muse, mutect2, varscan2
- MIA3 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 80/206 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs372980758; called by muse, mutect2, varscan2
- MLIP | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 75/145 reads (52%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.481); catalogued as rs368458090; called by muse, mutect2, varscan2
- MMEL1 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 25/378 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as rs758215874, COSV56523061; called by muse, mutect2
- MMP28 | c.953C>T p.T318M | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as rs370540313; called by muse, mutect2, varscan2
- MUC5AC | c.1189G>A p.V397I | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT tolerated (0.22); catalogued as rs371703006; called by muse, mutect2, varscan2
- MUC5B | c.6496G>A p.A2166T | Missense Mutation (SNP) | VAF 233/381 reads (61%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs772290629; called by mutect2, varscan2
- MYBPC2 | c.1925del p.P642Rfs*34 | Frame Shift Del (DEL) | VAF 112/484 reads (23%) | catalogued as rs752111099; called by mutect2, pindel, varscan2
- MYH8 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 193/517 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs746955439, COSV67961899; called by muse, mutect2, varscan2
- MYO10 | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 246/539 reads (46%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as rs771326395; called by muse, mutect2, varscan2
- MYOM2 | c.3349G>A p.A1117T | Missense Mutation (SNP) | VAF 44/328 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV50704352, COSV50803291; called by muse, mutect2, varscan2
- MYORG | c.1793C>T p.A598V | Missense Mutation (SNP) | VAF 108/248 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.226); catalogued as rs748408658; called by muse, mutect2, varscan2
- NTF4 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.394); catalogued as rs764831671, COSV100032236; called by muse, mutect2, varscan2
- OR10P1 | c.272A>G p.Q91R | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1431878793; called by muse, mutect2
- PARD6G | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 158/408 reads (39%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.058); catalogued as rs1023458976; called by muse, mutect2, varscan2
- PC | c.1936dup p.A646Gfs*19 | Frame Shift Ins (INS) | VAF 55/283 reads (19%) | catalogued as rs776366810; called by mutect2, pindel, varscan2
- PCLO | c.1339G>T p.G447* | Nonsense Mutation (SNP) | VAF 163/392 reads (42%) | catalogued as COSV61665295; called by muse, mutect2, varscan2
- PDZRN4 | c.2696G>A p.R899Q (on ENST00000402685 / NM_001164595.2; = p.R641Q on NM_013377.4) | Missense Mutation (SNP) | VAF 88/333 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1471240360, COSV54195797; called by muse, mutect2, varscan2
- PHF14 | c.946del p.M316Wfs*5 | Frame Shift Del (DEL) | VAF 75/230 reads (33%) | catalogued as COSV68854594; called by mutect2, pindel, varscan2
- PLEKHG4B | c.2330del p.P777Rfs*30 (on ENST00000283426; = p.P1133Rfs*30 on NM_052909.5) | Frame Shift Del (DEL) | VAF 39/369 reads (11%) | catalogued as rs746346365, COSV52056100; called by mutect2, pindel
- POLRMT | c.1688G>A p.R563Q | Missense Mutation (SNP) | VAF 41/416 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs766864045; called by muse, mutect2
- PROS1 | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 115/303 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.039); catalogued as rs754518511; called by muse, mutect2, varscan2
- PTF1A | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1339056661, COSV64735082; called by muse, mutect2, varscan2
- RAVER1 | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 120/253 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as rs762051821; called by muse, mutect2, varscan2
- RELN | c.7406C>T p.T2469I | Missense Mutation (SNP) | VAF 20/301 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV58994155; called by muse, mutect2
- RGL1 | c.1034del p.K345Rfs*12 (on ENST00000360851 / NM_001297672.2; = p.K380Rfs*12 on NM_015149.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 25/228 reads (11%) | catalogued as rs1290470008; called by mutect2, pindel, varscan2
- RNF128 | c.41G>A p.G14D | Missense Mutation (SNP) | VAF 17/374 reads (5%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as rs1324148514; called by muse, mutect2
- ROBO3 | c.571del p.R191Afs*31 | Frame Shift Del (DEL) | VAF 64/241 reads (27%) | catalogued as rs756837590; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- SETBP1 | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs776221622; called by muse, mutect2, varscan2
- SLC16A7 | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 49/333 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.386); catalogued as rs150567250; called by muse, mutect2, varscan2
- SLC31A2 | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 74/225 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199500515; called by muse, mutect2, varscan2
- SLC4A5 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 87/271 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs745602085; called by muse, mutect2, varscan2
- SLC66A1 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 76/236 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs753866294, COSV64321323; called by muse, mutect2, varscan2
- SLC7A14 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 86/177 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs750600837, COSV51586002; called by muse, mutect2, varscan2
- SLC7A8 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 143/293 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765572176, COSV100382212, COSV57553011; called by muse, mutect2, varscan2
- SLIT3 | c.4021G>A p.G1341S | Missense Mutation (SNP) | VAF 241/547 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); catalogued as rs145461439; called by muse, mutect2, varscan2
- STX11 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 71/385 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs758706076; called by muse, mutect2, varscan2
- SULF1 | c.1029del p.F343Lfs*7 | Frame Shift Del (DEL) | VAF 32/181 reads (18%) | catalogued as rs773014665, COSV52672549; called by mutect2, varscan2
- TACC2 | c.1661A>G p.K554R | Missense Mutation (SNP) | VAF 192/398 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs201967564; called by muse, mutect2, varscan2
- TACC2 | c.8548C>T p.R2850C (on ENST00000334433; = p.R928C on NM_006997.4) | Missense Mutation (SNP) | VAF 110/206 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761622230; called by muse, mutect2, varscan2
- TAF1 | c.5462C>T p.P1821L (on ENST00000373790 / NM_138923.4; = p.P1842L on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 139/525 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as rs763664628, COSV52110313; called by muse, mutect2, varscan2
- TDRD6 | c.4513A>G p.I1505V | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1309365007; called by muse, mutect2, varscan2
- TEAD2 | c.607del p.Q203Kfs*29 | Frame Shift Del (DEL) | VAF 36/114 reads (32%) | catalogued as rs752700410; called by mutect2, pindel, varscan2
- TEX2 | c.2047C>T p.R683* | Nonsense Mutation (SNP) | VAF 29/65 reads (45%) | catalogued as rs758281484, COSV99366667, COSV99367608; called by muse, mutect2, varscan2
- TG | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 135/1050 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373005597; called by muse, mutect2, varscan2
- TREML4 | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 126/253 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs750785182, COSV58384757; called by muse, mutect2, varscan2
- TSPAN32 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs756322762; called by muse, mutect2, varscan2
- WAS | c.1433G>A p.S478N | Missense Mutation (SNP) | VAF 179/464 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as CM144034; called by muse, mutect2, varscan2
- WDR64 | c.2722C>T p.R908* | Nonsense Mutation (SNP) | VAF 31/93 reads (33%) | catalogued as rs774228647, COSV63793828; called by muse, mutect2, varscan2
- ZC3H18 | c.2037del p.R680Gfs*5 | Frame Shift Del (DEL) | VAF 68/154 reads (44%) | catalogued as rs751577786; called by mutect2, varscan2
- ZNF346 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 7/189 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99993213; called by muse, mutect2
- ZNF626 | c.345dup p.G116Rfs*7 | Frame Shift Ins (INS) | VAF 46/149 reads (31%) | catalogued as rs782441698; called by mutect2, varscan2
- ZNF668 | c.1543del p.Q515Sfs*14 | Frame Shift Del (DEL) | VAF 65/177 reads (37%) | catalogued as rs760397907; called by mutect2, pindel, varscan2
- ACVR2B | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 286/681 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ADAM21 | c.2021G>A p.G674D | Missense Mutation (SNP) | VAF 17/591 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AKNAD1 | c.2501T>C p.L834P | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- ALDH1L1 | c.1645C>T p.Q549* | Nonsense Mutation (SNP) | VAF 6/136 reads (4%) | called by muse, mutect2
- AP3S1 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 55/243 reads (23%) | called by muse, mutect2, varscan2
- ATP7A | c.620A>G p.D207G | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- CAMTA2 | c.581G>A p.W194* | Nonsense Mutation (SNP) | VAF 58/136 reads (43%) | called by muse, mutect2, varscan2
- CCDC166 | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 75/325 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CDC5L | c.2375T>C p.L792P | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- CNBD2 | c.1670dup p.L558Ifs*22 (on ENST00000373973 / NM_001365709.1; = p.L554Ifs*22 on NM_080834.4) | Frame Shift Ins (INS) | VAF 114/355 reads (32%) | called by mutect2, pindel, varscan2
- COL1A2 | c.2674-8C>A | Splice Region (SNP) | VAF 170/377 reads (45%) | called by muse, mutect2, varscan2
- COL6A2 | c.2915C>T p.T972I | Missense Mutation (SNP) | VAF 29/350 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CPEB2 | c.22del p.V8Cfs*52 | Frame Shift Del (DEL) | VAF 42/131 reads (32%) | called by mutect2, pindel, varscan2
- DNAH17 | c.10496C>A p.P3499H | Missense Mutation (SNP) | VAF 131/381 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ELOVL5 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ELOVL6 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 219/497 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- EML1 | c.1621-1G>T p.X541_splice | Splice Site (SNP) | VAF 20/93 reads (22%) | called by muse, mutect2
- EPB41L3 | c.1298C>A p.S433* | Nonsense Mutation (SNP) | VAF 10/82 reads (12%) | called by muse, varscan2
- EVA1B | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 24/754 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2
- EXOC6 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EXT2 | c.322A>G p.I108V (on ENST00000343631; = p.I141V on NM_000401.3) | Missense Mutation (SNP) | VAF 287/670 reads (43%) | SIFT tolerated (0.84); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- F7 | c.73G>C p.A25P | Missense Mutation (SNP) | VAF 43/393 reads (11%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- FCHSD2 | c.2072C>T p.A691V | Missense Mutation (SNP) | VAF 150/341 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FPR1 | c.406C>A p.H136N | Missense Mutation (SNP) | VAF 121/299 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- FSIP2 | c.15456G>T p.E5152D | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- GALR2 | c.497A>C p.Q166P | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- GORASP2 | c.1123T>A p.S375T | Missense Mutation (SNP) | VAF 114/276 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GORASP2 | c.1124C>T p.S375F | Missense Mutation (SNP) | VAF 114/274 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- GRM3 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 13/445 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.13); called by muse, mutect2
- GTPBP1 | c.316T>C p.Y106H | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2
- HIC1 | c.1183G>A p.D395N (on ENST00000322941 / NM_001098202.1; = p.D376N on NM_006497.4) | Missense Mutation (SNP) | VAF 17/233 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.32); called by muse, mutect2
- INPP4A | c.2890C>T p.H964Y (on ENST00000074304 / NM_001134224.1; = p.H925Y on NM_004027.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGAL | c.1295G>T p.R432L | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ITPKB | c.2174G>A p.R725H | Missense Mutation (SNP) | VAF 215/603 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- LTBP3 | c.662-3del | Splice Region (DEL) | VAF 16/150 reads (11%) | called by mutect2, pindel, varscan2
- MCCC1 | c.1588del p.A530Hfs*16 | Frame Shift Del (DEL) | VAF 52/361 reads (14%) | called by mutect2, pindel, varscan2
- MELTF | c.1250C>A p.A417D | Missense Mutation (SNP) | VAF 80/386 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- MFAP3 | c.692A>G p.Y231C | Missense Mutation (SNP) | VAF 18/307 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- MTAP | c.992G>T p.C331F | Missense Mutation (SNP) | VAF 5/80 reads (6%) | PolyPhen benign (0.169); called by muse, mutect2
- MYO15B | c.5666C>T p.T1889I | Missense Mutation (SNP) | VAF 87/200 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- NAV2 | c.3509C>G p.A1170G (on ENST00000396087 / NM_001244963.2; = p.A1147G on NM_145117.5) | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ORC2 | c.889T>A p.L297I | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- OSBP2 | c.1828G>T p.D610Y | Missense Mutation (SNP) | VAF 20/323 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PASD1 | c.2149C>A p.L717M | Missense Mutation (SNP) | VAF 11/235 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.042); called by muse, mutect2
- PCDHB2 | c.140T>C p.V47A | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PDS5A | c.3329A>G p.Q1110R | Missense Mutation (SNP) | VAF 39/346 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- PHF14 | c.546del p.K182Nfs*19 | Frame Shift Del (DEL) | VAF 74/194 reads (38%) | called by mutect2, varscan2
- PI15 | c.479G>T p.R160I | Missense Mutation (SNP) | VAF 99/661 reads (15%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- PIK3R1 | c.1359_1376del p.N453_E458del (on ENST00000521381 / NM_181523.3; = p.N183_E188del on NM_181504.4) | In Frame Del (DEL) | VAF 21/94 reads (22%) | called by mutect2, pindel, varscan2
- PLEKHA3 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- PNISR | c.2250dup p.H751Tfs*5 | Frame Shift Ins (INS) | VAF 49/144 reads (34%) | called by mutect2, pindel, varscan2
- POLR3B | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 146/391 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRG3 | c.148T>G p.L50V | Missense Mutation (SNP) | VAF 113/240 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- PRKDC | c.12110del p.N4037Ifs*15 | Frame Shift Del (DEL) | VAF 54/421 reads (13%) | called by mutect2, pindel, varscan2
- PSD3 | c.2240del p.K747Sfs*73 (on ENST00000440756; = p.K746Sfs*73 on NM_015310.4) | Frame Shift Del (DEL) | VAF 38/256 reads (15%) | called by mutect2, varscan2
- PSD4 | c.2455A>G p.K819E | Missense Mutation (SNP) | VAF 99/222 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RB1 | c.45_70del p.E19Pfs*3 | Frame Shift Del (DEL) | VAF 83/128 reads (65%) | called by pindel, varscan2
- RHEBL1 | c.53-6C>A | Splice Region (SNP) | VAF 11/209 reads (5%) | called by muse, mutect2
- RYR2 | c.14902T>A p.*4968Kext*68 | Nonstop Mutation (SNP) | VAF 15/130 reads (12%) | called by muse, mutect2, varscan2
- SCLT1 | c.773del p.K258Rfs*27 | Frame Shift Del (DEL) | VAF 61/201 reads (30%) | called by mutect2, pindel, varscan2
- SEMA3B | c.1997C>T p.T666M | Missense Mutation (SNP) | VAF 32/580 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.238); called by muse, mutect2
- SET | c.243del p.Q82Rfs*6 (on ENST00000372692 / NM_001374326.1; = p.Q69Rfs*6 on NM_003011.4) | Frame Shift Del (DEL) | VAF 53/216 reads (25%) | called by mutect2, pindel, varscan2
- SGIP1 | c.635A>G p.Q212R | Missense Mutation (SNP) | VAF 78/191 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SHROOM4 | c.3941del p.K1314Rfs*23 | Frame Shift Del (DEL) | VAF 72/290 reads (25%) | called by mutect2, varscan2
- SLC2A13 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 59/385 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC7A13 | c.284dup p.L95Ffs*23 | Frame Shift Ins (INS) | VAF 115/834 reads (14%) | called by mutect2, pindel, varscan2
- SLC7A14 | c.1612G>T p.G538W | Missense Mutation (SNP) | VAF 84/176 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- SNX13 | c.2075_2076del p.F692Cfs*16 | Frame Shift Del (DEL) | VAF 22/79 reads (28%) | called by mutect2, pindel, varscan2
- SOX1 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 90/283 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SPTBN1 | c.3950A>G p.Q1317R | Missense Mutation (SNP) | VAF 100/283 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- SRP9 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- SYT11 | c.1184G>T p.R395M | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TIMMDC1 | c.227A>G p.N76S | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRIM9 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 34/38 reads (89%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- XRN2 | c.740A>C p.N247T | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- ZKSCAN3 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 18/360 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- ZNF493 | c.174del p.K58Nfs*100 | Frame Shift Del (DEL) | VAF 76/222 reads (34%) | called by mutect2, pindel, varscan2
- ZNF628 | c.3038C>T p.A1013V | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF703 | c.264dup p.A90Gfs*141 | Frame Shift Ins (INS) | VAF 54/382 reads (14%) | called by mutect2, pindel, varscan2
- ZNF787 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 98/212 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- AHNAK2 | c.9510G>A p.A3170= | Silent (SNP) | VAF 38/680 reads (6%) | catalogued as rs754492501; called by muse, mutect2
- AMER1 | c.3351T>C p.G1117= | Silent (SNP) | VAF 60/161 reads (37%) | called by muse, mutect2, varscan2
- ASB11 | c.123C>G p.V41= | Silent (SNP) | VAF 13/70 reads (19%) | called by muse, mutect2, varscan2
- ATXN3L | c.837G>A p.P279= | Silent (SNP) | VAF 43/404 reads (11%) | catalogued as rs750576834, COSV66075872; called by muse, mutect2, varscan2
- ATXN3L | c.219T>C p.G73= | Silent (SNP) | VAF 55/245 reads (22%) | called by muse, mutect2, varscan2
- BACH2 | c.73C>T p.L25= | Silent (SNP) | VAF 175/417 reads (42%) | called by muse, mutect2, varscan2
- BCAS1 | c.390G>A p.A130= | Silent (SNP) | VAF 193/468 reads (41%) | catalogued as rs768968211; called by muse, mutect2, varscan2
- BHLHE22 | c.990A>T p.A330= | Silent (SNP) | VAF 195/1772 reads (11%) | called by muse, mutect2, varscan2
- BICDL2 | c.915C>T p.D305= | Silent (SNP) | VAF 15/399 reads (4%) | catalogued as rs1343408555; called by muse, mutect2
- C3orf18 | c.96C>T p.S32= | Silent (SNP) | VAF 194/475 reads (41%) | catalogued as rs200572019; called by muse, mutect2, varscan2
- CALHM2 | c.579C>T p.G193= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as rs753005980; called by muse, mutect2, varscan2
- CCDC97 | c.213C>T p.A71= | Silent (SNP) | VAF 66/656 reads (10%) | catalogued as rs373386903; called by muse, mutect2, varscan2
- CD101 | c.876C>T p.S292= | Silent (SNP) | VAF 58/132 reads (44%) | called by mutect2, varscan2
- CDH23 | c.519C>G p.P173= | Silent (SNP) | VAF 103/213 reads (48%) | called by muse, mutect2, varscan2
- CDKL5 | c.2085A>G p.T695= | Silent (SNP) | VAF 13/281 reads (5%) | called by muse, mutect2
- CELF2 | c.261C>T p.F87= (on ENST00000416382 / NM_001025077.3; = p.F94= on NM_006561.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 47/120 reads (39%) | catalogued as rs1565364868; called by muse, mutect2, varscan2
- CFAP99 | c.879C>T p.I293= | Silent (SNP) | VAF 58/238 reads (24%) | called by muse, mutect2, varscan2
- CILP | c.555C>T p.C185= | Silent (SNP) | VAF 43/226 reads (19%) | called by muse, mutect2, varscan2
- CPNE5 | c.228C>T p.F76= | Silent (SNP) | VAF 90/249 reads (36%) | catalogued as rs574969645, COSV55195626; called by muse, mutect2, varscan2
- DIAPH3 | c.3249G>A p.P1083= (on ENST00000400324 / NM_001042517.2; = p.P820= on NM_030932.3) | Silent (SNP) | VAF 185/479 reads (39%) | catalogued as rs371902789; called by muse, mutect2, varscan2
- DPH1 | c.321C>T p.Y107= | Silent (SNP) | VAF 93/345 reads (27%) | catalogued as rs749536371, COSV53984185; called by muse, mutect2, varscan2
- ELP1 | c.2379G>T p.T793= | Silent (SNP) | VAF 162/388 reads (42%) | catalogued as rs1158825223, COSV65896226; called by muse, mutect2, varscan2
- EPOP | c.315C>T p.G105= | Silent (SNP) | VAF 54/122 reads (44%) | called by muse, mutect2, varscan2
- GDF1 | c.525C>T p.G175= | Silent (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2
- GRIK3 | c.714G>A p.A238= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as rs755346757, COSV100902484; called by muse, mutect2
- GUCY2F | c.951G>A p.E317= | Silent (SNP) | VAF 26/342 reads (8%) | called by muse, mutect2
- HDAC6 | c.1752C>T p.G584= | Silent (SNP) | VAF 117/259 reads (45%) | catalogued as rs782108376; called by muse, mutect2, varscan2
- HIVEP1 | c.7419C>T p.R2473= | Silent (SNP) | VAF 88/193 reads (46%) | catalogued as rs374507026; called by muse, mutect2, varscan2
- HSF1 | c.475C>T p.L159= | Silent (SNP) | VAF 71/364 reads (20%) | catalogued as rs1277652825; called by muse, mutect2, varscan2
- IRX2 | c.402C>T p.N134= | Silent (SNP) | VAF 201/417 reads (48%) | catalogued as rs771720742, COSV57413383; called by muse, mutect2, varscan2
- KIAA1210 | c.4611C>T p.Y1537= | Silent (SNP) | VAF 110/239 reads (46%) | catalogued as rs773445783, COSV68175489; called by muse, mutect2, varscan2
- KIAA1522 | c.1774T>C p.L592= (on ENST00000373480 / NM_001198972.2; = p.L651= on NM_020888.3) | Silent (SNP) | VAF 52/123 reads (42%) | called by muse, mutect2, varscan2
- KIF9 | c.1179T>C p.A393= | Silent (SNP) | VAF 12/230 reads (5%) | called by muse, mutect2
- LAMA5 | c.10776G>A p.T3592= | Silent (SNP) | VAF 135/305 reads (44%) | catalogued as rs747210883; called by muse, mutect2, varscan2
- LTBP1 | c.2259A>G p.G753= (on ENST00000404816 / NM_206943.4; = p.G427= on NM_000627.4) | Silent (SNP) | VAF 15/394 reads (4%) | called by muse, mutect2
- MAEA | c.1074C>T p.N358= (on ENST00000303400 / NM_001017405.3; = p.N317= on NM_005882.5) | Silent (SNP) | VAF 72/165 reads (44%) | catalogued as rs142683395; called by muse, mutect2, varscan2
- MINPP1 | c.1116G>A p.E372= | Silent (SNP) | VAF 67/167 reads (40%) | catalogued as rs766332890; called by muse, mutect2
- NBAS | c.4080G>A p.L1360= | Silent (SNP) | VAF 109/267 reads (41%) | called by muse, mutect2, varscan2
- OR10P1 | c.510C>T p.R170= | Silent (SNP) | VAF 167/504 reads (33%) | called by muse, mutect2, varscan2
- OR52M1 | c.516T>C p.Y172= | Silent (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- PDHA1 | c.711A>C p.A237= | Silent (SNP) | VAF 210/524 reads (40%) | called by muse, mutect2, varscan2
- PHF12 | c.1989C>A p.P663= | Silent (SNP) | VAF 7/127 reads (6%) | called by muse, mutect2
- PIEZO2 | c.5538C>T p.D1846= | Silent (SNP) | VAF 152/357 reads (43%) | catalogued as rs539810112; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRPH | c.105G>A p.S35= | Silent (SNP) | VAF 136/308 reads (44%) | called by muse, mutect2, varscan2
- RBCK1 | c.882C>T p.A294= (on ENST00000356286 / NM_031229.4; = p.A252= on NM_006462.6) | Silent (SNP) | VAF 125/330 reads (38%) | catalogued as rs760320592; called by muse, mutect2, varscan2
- SLC16A14 | c.891C>T p.F297= | Silent (SNP) | VAF 112/275 reads (41%) | catalogued as rs767433269, COSV54620560; called by muse, mutect2, varscan2
- SLC2A13 | c.949C>T p.L317= | Silent (SNP) | VAF 69/143 reads (48%) | called by muse, mutect2, varscan2
- SLC4A10 | c.2823G>A p.V941= (on ENST00000446997 / NM_001354461.2; = p.V911= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 84/203 reads (41%) | called by muse, mutect2, varscan2
- SLC8A2 | c.2211C>T p.F737= | Silent (SNP) | VAF 75/229 reads (33%) | catalogued as rs1389550086, COSV52638972; called by muse, mutect2, varscan2
- SLFN14 | c.300G>A p.Q100= | Silent (SNP) | VAF 13/231 reads (6%) | catalogued as rs1335315024, COSV101334711; called by muse, mutect2
- SOGA3 | c.2583C>T p.D861= | Silent (SNP) | VAF 195/527 reads (37%) | catalogued as rs374876819, COSV64105653; called by muse, mutect2, varscan2
- SP4 | c.459C>G p.V153= | Silent (SNP) | VAF 93/230 reads (40%) | called by muse, mutect2, varscan2
- SUFU | c.855C>T p.D285= | Silent (SNP) | VAF 73/261 reads (28%) | catalogued as rs200206997, COSV100883139; ClinVar: likely benign; called by muse, mutect2, varscan2
- TBATA | c.669C>T p.L223= | Silent (SNP) | VAF 81/166 reads (49%) | catalogued as COSV100165318; called by muse, mutect2, varscan2
- TIGD3 | c.297G>A p.G99= | Silent (SNP) | VAF 95/484 reads (20%) | catalogued as rs373026238, COSV52890113; called by muse, mutect2, varscan2
- TMEM161A | c.1140G>T p.T380= | Silent (SNP) | VAF 99/298 reads (33%) | called by muse, mutect2, varscan2
- TOP3B | c.99C>T p.N33= | Silent (SNP) | VAF 17/185 reads (9%) | catalogued as rs774675032; called by muse, mutect2
- TRAPPC9 | c.1899G>A p.A633= | Silent (SNP) | VAF 116/1532 reads (8%) | catalogued as rs200082053; called by muse, mutect2
- TUFM | c.345T>C p.H115= | Silent (SNP) | VAF 50/602 reads (8%) | catalogued as rs745598449; called by muse, mutect2
- UPF1 | c.270C>T p.D90= | Silent (SNP) | VAF 95/279 reads (34%) | catalogued as rs770043525; called by muse, mutect2, varscan2
- UQCRC1 | c.423G>A p.P141= | Silent (SNP) | VAF 62/216 reads (29%) | catalogued as rs746906806, COSV52551498; called by muse, mutect2, varscan2
- VPS28 | c.279C>T p.D93= | Silent (SNP) | VAF 109/617 reads (18%) | catalogued as rs371935147; called by muse, mutect2, varscan2
- XPC | c.1302T>C p.S434= | Silent (SNP) | VAF 12/276 reads (4%) | called by muse, mutect2
- ZFHX4 | c.10468T>C p.L3490= | Silent (SNP) | VAF 472/628 reads (75%) | called by muse, mutect2, varscan2
- ZNF747 | c.213C>T p.G71= | Silent (SNP) | VAF 20/465 reads (4%) | called by muse, mutect2
- ABI3BP | c.1576+17943G>A | Intron (SNP) | VAF 15/302 reads (5%) | called by muse, mutect2
- AC058822.1 | c.1018-288129G>A | Intron (SNP) | VAF 15/134 reads (11%) | called by muse, mutect2, varscan2
- ADAM2 | c.-3G>A | 5'UTR (SNP) | VAF 32/724 reads (4%) | called by muse, mutect2
- AK9 | c.3633+13_3633+15del | Intron (DEL) | VAF 32/137 reads (23%) | catalogued as rs201441562; called by pindel, varscan2
- C10orf95 | c.*90A>G | 3'UTR (SNP) | VAF 14/404 reads (3%) | called by muse, mutect2
- C11orf96 | chr11:43943371 G>A | 3'Flank (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- C8orf31 | n.447C>T | RNA (SNP) | VAF 75/395 reads (19%) | catalogued as rs538935958; called by muse, mutect2, varscan2
- CELF4 | c.657+40C>T | Intron (SNP) | VAF 10/270 reads (4%) | called by muse, mutect2
- CIDEA | c.38+46T>C | Intron (SNP) | VAF 5/87 reads (6%) | called by muse, mutect2
- COPS9 | chr2:240126868 del C | 3'Flank (DEL) | VAF 113/333 reads (34%) | catalogued as COSV56228819; called by mutect2, pindel, varscan2
- CYP2C8 | c.331+48del | Intron (DEL) | VAF 126/375 reads (34%) | called by mutect2, pindel, varscan2
- DOCK4 | c.1066+57del | Intron (DEL) | VAF 73/398 reads (18%) | catalogued as rs762024473; called by mutect2, varscan2
- GPI | chr19:34364998 C>T | 5'Flank (SNP) | VAF 8/194 reads (4%) | called by muse, mutect2
- GSS | c.1301+34T>C | Intron (SNP) | VAF 160/378 reads (42%) | called by muse, mutect2, varscan2
- HLA-E | c.64+48G>T | Intron (SNP) | VAF 29/95 reads (31%) | called by muse, mutect2, varscan2
- HTR3A | c.917-15C>A | Intron (SNP) | VAF 126/292 reads (43%) | called by muse, mutect2, varscan2
- MIR18B | n.59G>A | RNA (SNP) | VAF 40/113 reads (35%) | called by muse, mutect2, varscan2
- MRPL37 | chr1:54220818 C>A | 3'Flank (SNP) | VAF 64/305 reads (21%) | called by muse, mutect2, varscan2
- NDRG1 | c.*19G>A | 3'UTR (SNP) | VAF 33/280 reads (12%) | catalogued as rs758152678, COSV100105786; called by muse, mutect2, varscan2
- OBSCN | c.11660-2515C>T | Intron (SNP) | VAF 140/361 reads (39%) | catalogued as rs373362308, COSV99480005; called by muse, mutect2, varscan2
- OTUD7A | c.151+5299G>A | Intron (SNP) | VAF 54/134 reads (40%) | catalogued as rs1439463726; called by muse, mutect2, varscan2
- PCYT1B | c.*149A>G | 3'UTR (SNP) | VAF 62/237 reads (26%) | called by muse, mutect2, varscan2
- PLEKHA8P1 | n.1470G>T | RNA (SNP) | VAF 218/536 reads (41%) | called by muse, mutect2, varscan2
- PQBP1 | chrX:48897783 del C | 5'Flank (DEL) | VAF 99/257 reads (39%) | called by mutect2, pindel, varscan2
- SMPD4BP | n.2490C>T | RNA (SNP) | VAF 43/552 reads (8%) | catalogued as rs764352179; called by muse, mutect2
- TCF15 | c.*58C>T | 3'UTR (SNP) | VAF 17/390 reads (4%) | called by muse, mutect2
- TSPO | c.*66G>A | 3'UTR (SNP) | VAF 86/186 reads (46%) | catalogued as rs746491832, COSV99333717; called by muse, mutect2, varscan2
- UMPS | c.*4457A>G | 3'UTR (SNP) | VAF 12/314 reads (4%) | called by muse, mutect2
- ZSWIM4 | chr19:13836333 T>C | 3'Flank (SNP) | VAF 77/399 reads (19%) | called by muse, mutect2, varscan2
